Somatic mutation profile of tumor specimen ALCH-B2BH-TTP1-B (aliquot ALCH-B2BH-TTP1-B-1-0-D-A76N-36) from ALCHEMIST case ALCH-B2BH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.8 years (23,683 days).
Specimen ALCH-B2BH-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f8b0e5d-6ead-4ee5-b3d2-557360be8971.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2BH-NB1-A (Blood Derived Normal), aliquot ALCH-B2BH-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dceb8bf3-0310-4cca-a0ae-7d0253a7e3e6

The open-access MAF lists 89 somatic variants for this specimen: 59 protein-altering or splice-affecting, 20 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 20, Splice Site 4, Intron 4, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 2, 5'UTR 2, 3'UTR 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 32/333 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 53/273 reads (19%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ALOX12B | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 118/420 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757119807; called by muse, varscan2
- ATP8B1 | c.2677G>C p.D893H | Missense Mutation (SNP) | VAF 26/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM117163, COSV52178989; called by muse, mutect2
- CCDC148 | c.148-1G>C p.X50_splice | Splice Site (SNP) | VAF 36/361 reads (10%) | catalogued as COSV51755587; called by muse, mutect2
- COL4A3 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 62/494 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367868483; called by muse, mutect2, varscan2
- DCAF12L2 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV100758476, COSV63584129; called by muse, mutect2, varscan2
- ERBB2 | c.2263T>G p.L755V | Missense Mutation (SNP) | VAF 32/335 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV54062219, COSV54066696; called by muse, mutect2, varscan2
- ERG28 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 62/717 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746304122, COSV56363496; called by muse, mutect2
- GBE1 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 98/384 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168126093; called by muse, mutect2, varscan2
- GLRA3 | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56864626; called by muse, mutect2, varscan2
- HDC | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 155/1027 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV51078750; called by muse, mutect2, varscan2
- KIAA1549L | c.3522G>T p.K1174N (on ENST00000321505; = p.K1471N on NM_012194.3) | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99682829; called by muse, mutect2, varscan2
- MAPT | c.1097G>T p.R366L (on ENST00000262410 / NM_001377265.1; = p.R291L on NM_016835.4) | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV52243191, COSV52243253; called by muse, mutect2, varscan2
- MIB2 | c.3208G>A p.V1070M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61543558; called by muse, varscan2
- MYOF | c.3115G>A p.A1039T | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs973303600, COSV63700757; called by muse, mutect2, varscan2
- NCAPD3 | c.3662G>A p.R1221Q | Missense Mutation (SNP) | VAF 36/604 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs751116530, COSV73187875; called by muse, mutect2
- PBRM1 | c.3046G>T p.E1016* (on ENST00000296302 / NM_001366071.2; = p.E991* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 13/310 reads (4%) | catalogued as COSV56276607, COSV56300412; called by muse, mutect2
- PLEKHO2 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 24/474 reads (5%) | catalogued as rs1432136072, COSV60262701; called by muse, mutect2
- POGLUT3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as rs775203476; called by muse, mutect2
- PVR | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs375970875; called by muse, varscan2
- SCN3A | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 40/899 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751290489; called by muse, mutect2
- SCNN1D | c.535C>T p.P179S (on ENST00000338555; = p.P343S on NM_001130413.4) | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1391452543; called by muse, mutect2
- SERPINA11 | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 72/1027 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58242582; called by muse, mutect2
- SLIT2 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs756812021, COSV56571632; called by muse, mutect2
- ZFHX3 | c.6482G>T p.R2161L | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99195421; called by muse, mutect2
- ZNF280B | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs775832286, COSV100840220, COSV99081441; called by muse, mutect2, varscan2
- ACO1 | c.372A>G p.I124M | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- AKAP12 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 18/359 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- ANK2 | c.9317G>T p.G3106V | Missense Mutation (SNP) | VAF 44/812 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATXN2L | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 92/409 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- BZW1 | c.422del p.G141Vfs*10 | Frame Shift Del (DEL) | VAF 39/335 reads (12%) | called by mutect2, pindel, varscan2
- CARS2 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CDA | c.342del p.V115Cfs*3 | Frame Shift Del (DEL) | VAF 79/599 reads (13%) | called by mutect2, pindel, varscan2
- CENPE | c.3687+1G>T p.X1229_splice | Splice Site (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- CHD6 | c.3107C>T p.A1036V | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DOCK6 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ERAP1 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 137/697 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXL20 | c.102dup p.R35Tfs*30 | Frame Shift Ins (INS) | VAF 30/172 reads (17%) | called by mutect2, pindel, varscan2
- GMIP | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- GPR179 | c.6586C>A p.P2196T (on ENST00000621958; = p.P2195T on NM_001004334.4) | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- GTPBP4 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- LONRF2 | c.1476+1G>C p.X492_splice | Splice Site (SNP) | VAF 56/283 reads (20%) | called by muse, varscan2
- LOXL2 | c.1133dup p.S379Lfs*21 | Frame Shift Ins (INS) | VAF 16/176 reads (9%) | called by mutect2, pindel
- MEN1 | c.260_261insG p.A88Rfs*29 | Frame Shift Ins (INS) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- MLYCD | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 23/315 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.576); called by muse, mutect2
- MRE11 | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 105/694 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- MUC2 | c.2362G>T p.A788S | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT tolerated (0.75); called by muse, mutect2, varscan2
- MYH1 | c.1394T>A p.I465N | Missense Mutation (SNP) | VAF 163/683 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO7A | c.5383C>A p.L1795I | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- PGBD2 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- RERGL | c.228G>T p.W76C | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMS2 | c.2629G>A p.E877K (on ENST00000666250 / NM_001348490.2; = p.E685K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/450 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TMCC2 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TUBAL3 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 86/452 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- XPNPEP1 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 40/764 reads (5%) | called by muse, mutect2
- ZAN | c.5551C>G p.Q1851E | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF226 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.031); called by muse, varscan2
- ZNF675 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 50/559 reads (9%) | called by muse, mutect2
- ADGRF2 | c.174T>A p.G58= | Silent (SNP) | VAF 64/417 reads (15%) | called by muse, varscan2
- BCAN | c.2157C>T p.Y719= | Silent (SNP) | VAF 51/233 reads (22%) | catalogued as rs1161535321; called by muse, mutect2, varscan2
- CHRFAM7A | c.270G>T p.L90= | Silent (SNP) | VAF 94/1309 reads (7%) | called by muse, mutect2
- CMPK2 | c.1056G>A p.L352= | Silent (SNP) | VAF 15/445 reads (3%) | catalogued as COSV56774028, COSV99879014; called by muse, mutect2
- CNTNAP2 | c.2928T>C p.N976= | Silent (SNP) | VAF 188/924 reads (20%) | catalogued as rs765953292, COSV62263545; ClinVar: likely benign; called by muse, varscan2
- CYP11B2 | c.231C>T p.P77= | Silent (SNP) | VAF 62/428 reads (14%) | called by muse, mutect2, varscan2
- CYP46A1 | c.1041G>T p.L347= | Silent (SNP) | VAF 35/503 reads (7%) | called by muse, mutect2
- GDF2 | c.660C>A p.T220= | Silent (SNP) | VAF 73/526 reads (14%) | called by muse, mutect2, varscan2
- GLRA3 | c.813C>G p.S271= | Silent (SNP) | VAF 63/375 reads (17%) | catalogued as COSV99926869; called by muse, mutect2, varscan2
- GMIP | c.495G>T p.L165= | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as COSV52559150, COSV99179309; called by muse, mutect2, varscan2
- IFT80 | c.1761A>G p.P587= | Silent (SNP) | VAF 42/443 reads (9%) | catalogued as rs147387605; called by muse, mutect2
- KRT78 | c.471C>T p.G157= | Silent (SNP) | VAF 46/473 reads (10%) | called by muse, mutect2, varscan2
- MAGEA12 | c.312C>T p.S104= | Silent (SNP) | VAF 87/294 reads (30%) | called by muse, mutect2, varscan2
- MAP4K1 | c.2025C>T p.I675= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- PHYKPL | c.654G>A p.V218= | Silent (SNP) | VAF 47/323 reads (15%) | catalogued as COSV100069666; called by muse, mutect2, varscan2
- SCN7A | c.2670A>T p.G890= | Silent (SNP) | VAF 38/331 reads (11%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.1425T>C p.D475= | Silent (SNP) | VAF 84/396 reads (21%) | called by muse, mutect2, varscan2
- SYNE1 | c.3975G>A p.E1325= (on ENST00000367255 / NM_182961.4; = p.E1332= on NM_033071.3) | Silent (SNP) | VAF 66/392 reads (17%) | catalogued as rs372832470; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SYT16 | c.603C>T p.S201= | Silent (SNP) | VAF 36/624 reads (6%) | catalogued as rs953514244, COSV70856123, COSV70856245; called by muse, mutect2
- THPO | c.582C>T p.H194= (on ENST00000649095 / NM_001290003.1; = p.H54= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 70/504 reads (14%) | catalogued as rs757828255; called by muse, mutect2, varscan2
- ACSF3 | c.1367-66C>A | Intron (SNP) | VAF 98/607 reads (16%) | called by muse, mutect2, varscan2
- ADAP2 | c.-2C>T | 5'UTR (SNP) | VAF 3/47 reads (6%) | catalogued as rs1282097329; called by muse, mutect2
- C3P1 | n.3003G>A | RNA (SNP) | VAF 21/317 reads (7%) | catalogued as rs530921353; called by muse, mutect2
- HOXB6 | c.-78-2274G>T | Intron (SNP) | VAF 117/699 reads (17%) | called by muse, mutect2, varscan2
- NIBAN3 | c.1844-1507C>T | Intron (SNP) | VAF 16/234 reads (7%) | catalogued as rs775474454, COSV53111165; called by muse, mutect2
- PHYKPL | c.*15G>C | 3'UTR (SNP) | VAF 22/396 reads (6%) | catalogued as COSV57425069; called by muse, mutect2
- PJVK | c.-42G>A | 5'UTR (SNP) | VAF 31/429 reads (7%) | called by muse, mutect2
- PLCD1 | c.1446+49C>A | Intron (SNP) | VAF 49/169 reads (29%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159320 G>T | 5'Flank (SNP) | VAF 6/38 reads (16%) | catalogued as rs201829623; called by muse, mutect2, varscan2
- ZMIZ1 | c.*1364C>T | 3'UTR (SNP) | VAF 22/544 reads (4%) | called by muse, mutect2
